Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3362, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3362-01A (Primary Tumor).

[page 1 of 2]
**TEST: Surgical Pathology**

Collected Date & Time: [REDACTED]

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

Pre-Op Diagnosis

Cholelithiasis, left renal mass

Post-Op Diagnosis

Same as above

Clinical History

Same as above

Gross Description:

Two parts

Container labeled [REDACTED] 1 - gallbladder" is a 6.1 x 2.7 x 2.6 cm previously partially opened gallbladder having a smooth bile stained serosa. The wall measures up to 0.1 cm and is fibrotic. The lumen is lined by trabeculated bile stained mucosa. Within the lumen is a minimal amount of viscid deep green bile; as well as multiple firm friable multi-faceted gray brown calculi measuring individually up to 0.6 cm and measuring in aggregate 6.4 x 3.6 x 0.6 cm. Representative sections are submitted in a single cassette.

Container labeled [REDACTED] 2 - left kidney" is a 283 gram previously partially sectioned left nephrectomy specimen surrounded by a moderate amount of perinephric adipose tissue faced anteriorly by a minimal amount of Gerota's fascia. The specimen on reconstruction measures as received 16.8 x 8.2 x 6.0 cm. Noted in the surrounding adipose tissue is a 5.2 x 2.6 x 2.2 cm recognizable intact renal gland which on sectioning has a bright yellow cortex measuring up to 0.1 cm surrounding a tan gray medulla. The margins include 0.9 cm of grossly patent renal artery, 0.6 cm of grossly patent renal vein, and 5.6 cm of grossly patent ureter. The capsule strips with ease to reveal an organ measuring 10.0 x 6.7 x 5.7 cm. The cortex is smooth, slightly lobulated, and gray tan to brown. Extending beyond the plane of the cortex on the posterior lateral mid region of the specimen is a well circumscribed 3.3 x 3.3 x 2.9 cm nodular lesion having a slightly bulging hemorrhagic gray pink to yellow cut surface. This is covered on the outer aspect by a thin layer of attenuated parenchyma which is grossly intact. The lesion does not grossly appear to extend into the surrounding adipose tissue. The remaining cortex measures up to 0.8 cm and is slightly pale homogenous pink red to brown. The cortical medullary junction is poorly defined. The medulla is pink red to brown with sharp papillae. The calices and pelvis are lined by smooth tan white mucosa. No gross lesions are identified within the surrounding adipose tissue.

Also received in the same container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted labeled as follows: A - vascular and ureteral margins, B through F - representative lesion and surrounding tissue, G - random uninvolved parenchyma, H - representative adrenal gland.

Microscopic Description:

The slides labeled [REDACTED] are examined. See diagnosis.

Final Diagnosis

Gallbladder (cholecystectomy):

Chronic cholecystitis and cholelithiasis. PAS 6,2

Left kidney (nephrectomy):

Tumor characteristics:

1. Histologic type: Renal cell carcinoma, clear cell type.
2. Tumor site: Left kidney, mid region.

[page 2 of 2]
3. Size: 3.3 x 3.3 x 2.9 cm in greatest dimensions.
4. Macroscopic extent of tumor: Tumor limited to kidney.
5. Nuclear grade: Fuhrman grade 2/4.
6. Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified.
7. Transcapsular invasion: No.
8. Renal vein invasion: No.
9. Vena caval invasion: Not resected.
10. Adrenal gland: Not involved.
- Surgical margin status:
1. Soft tissue margin: Not involved.
2. Ureteral margin: Negative.
3. Vascular margins: Negative.

Lymph node status:

No lymph nodes resected. PAS 9 SPC-A
CPT: 88304, 88307

Comments

This test has been finalized at the [REDACTED] Campus.

[REDACTED]

Source: NCI Genomic Data Commons file bd2cb550-8bca-4208-bab1-6b9b8f83b15e (TCGA-A3-3362.1C03E3CC-D321-417A-964C-CCFC620FAC3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).